FM case AD14000 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/070789a8-a5cb-43c9-8c29-f5c3eb637c53

Male, 52.2 years: Carcinoma, NOS (ICD-O-3 8010/3); specimen biopsied or resected from the adrenal gland. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Tumor.
